Surgical pathology report (de-identified scan), TCGA case TCGA-UY-A9PH, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UY-A9PH-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED] Visit #: [REDACTED]
DOB: [REDACTED] Sex: Male
Soc. Sec. #: [REDACTED] Location: [REDACTED]
Physician(s): [REDACTED]

Accession #: [REDACTED]
Service Date: [REDACTED]
Received: [REDACTED]
Client: [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

ICD O-3
Carcinoma, urothelial NOS
8120/3
Site Bladder NOS
C67.9
03/30/14

- A. Ureter, right, excision: Negative for carcinoma.
- B. Ureter, left, excision: Negative for carcinoma.
- C. Urinary bladder and prostate, cystoprostatectomy:
- Urinary bladder:
1. Invasive urothelial carcinoma, high grade, 1.6 cm, negative margins; see comment.
2. Nephrogenic adenoma (slide C7).
3. Granulomatous inflammation of mucosa, consistent with BCG effect.
4. Three lymph nodes negative for carcinoma (0/3).
- Prostate:
1. Negative for tumor.
2. Granulomatous inflammation.
3. Benign prostatic hyperplasia.
- Seminal vesicles: No significant pathologic abnormality.
- D. Lymph nodes, right obturator, dissection: Nine lymph nodes negative for carcinoma (0/9).
- E. Lymph nodes, right internal iliac, dissection: Three lymph nodes negative for carcinoma (0/3).
- F. Lymph nodes, left internal iliac, dissection: Five lymph nodes negative for carcinoma (0/5).
- G. Lymph nodes, left obturator, dissection: Three lymph nodes negative for carcinoma (0/3).

[page 2 of 4]
[REDACTED]

H. Ureter, "final left distal," excision: Negative for carcinoma.

I. Ureter, "final right distal," excision: Negative for carcinoma.

COMMENT:

Bladder Tumor Synoptic Comment

- **Tumor type:** Urothelial carcinoma: Transitional cell.
- **Tumor grade:** High grade.
- **Tumor size:** 1.6 cm.
- **Extent of tumor in bladder:** Invasion into outer half of muscularis propria (slide C24).
- **Lymphatic/vascular invasion:** Present in lymphatics (slide C24).
- **Epithelial abnormalities in bladder:** The majority of the epithelium is denuded.
- **Extension of tumor into adjacent organs:** None.
- **Margins:**
- **Urethral margin:** Negative (invasive tumor is >1 cm from margin).
- **Right ureter margin:** Negative (tumor is >1 cm from margin).
- **Left ureter margin:** Negative (tumor is >1 cm from margin).
- **Perivesical margin:** Negative (tumor is 1.1 cm from margin, slide C26).
- **Lymph node status:** Negative. Total number of nodes examined: 20.
- **Other pathologic findings in bladder:** Nephrogenic adenoma, granulomatous inflammation.
- **AJCC/UICC stage:** pT2bN0.

Dr. [REDACTED] has reviewed selected slides and concurs with the diagnoses of urothelial carcinoma and nephrogenic adenoma.

Specimen(s) Received

A:Right ureter (FS)
B:Left ureter (FS)
C:Bladder and prostate, fs
D:Lymph node, right obturator
E:Lymph node, right internal iliac
F:Lymph node, left internal iliac
G:Lymph node, left obturator
H:Final left distal ureter
I:Final right distal ureter

Intraoperative Diagnosis

FS1 (A) Right ureter, biopsy: No tumor. [REDACTED]

FS2 (B) Left ureter, biopsy: No tumor. [REDACTED]

FS3 (C) Urethral margin, cystoprostatectomy: No tumor. ([REDACTED])

Clinical History

The patient is a [REDACTED]-year-old man who per the electronic medical record [REDACTED] a recent bladder biopsy [REDACTED] showed urothelial carcinoma that is suspicious for lamina propria invasion. He now undergoes a cystoprostatectomy with ileal conduit.

Gross Description

[REDACTED]

[page 3 of 4]
The specimen is received in nine parts, each labeled with the patient's name and medical record number. Parts A-C are received fresh. Parts D-I are received in formalin.

Part A, additionally labeled "right ureter," consists of one, soft, pink-white, ovoid, unoriented tissue fragment (0.5 x 0.5 x 0.2 cm). The entire specimen is frozen for frozen section diagnosis 1, and subsequently submitted in cassette A1.

Part B, additionally labeled "left ureter," consists of one, soft, pink-white, irregular, unoriented, ovoid tissue fragment (0.3 x 0.3 x 0.2 cm). The entire specimen is frozen for frozen section diagnosis 2, and subsequently submitted in cassette B1.

Part C is additionally labeled "bladder + prostate," and consists of a cystoprostatectomy specimen containing bladder (239.6 gm; 9 cm from right to left x 3.6 cm from anterior to posterior x 11.2 cm from superior to inferior) with attached ureters and prostate (3.1 cm from apex to base x 3.2 cm from left to right x 3 cm from anterior to posterior).

GROSS PATHOLOGIC FINDINGS: At the junction of the left inferior bladder and prostate there is a well-circumscribed, ovoid, firm, tan nodule (1.6 x 1.5 x 1 cm) that is located 1.1 cm from the left anterior resection surface. Within the mucosal surface of the bladder there are three indurated, red-brown areas. The first area is located in the right trigone (1.2 x 0.8 cm) and is located 4 cm from the urethral resection surface and 2 cm from the radial resection margin. The second indurated, red mucosal area (0.3 x 0.3 cm) is located in the posterior wall of the bladder and is located between the orifices of the ureter and is 5 cm from the urethral resection surface. The third indurated, red mucosal area (1.2 x 0.9 cm) is located in the left lateral wall of the bladder and is 5.3 cm from the urethral resection surface. The remaining portion of the uninvolved bladder appears unremarkable with red-pink, normal-appearing mucosa. The surrounding adipose tissue is extensively examined for lymph nodes with multiple firm tan-white candidate lymph nodes (0.3 cm in diameter) identified.

There is an irregular, yellow-tan area within the left mid gland of the prostate measuring 0.9 x 0.4 x 0.3 cm, and is confined to the prostate. The left seminal vesicle (2.9 x 2 x 0.7 cm) and the right seminal vesicle (2.5 x 2.2 x 0.8 cm) are firm tan-brown and appear unremarkable.

ORIENTED BY: Anatomic landmarks - bladder and prostate.

INTRAOPERATIVE EVALUATION: Frozen section of urethral margin, en face (FS1), submitted in cassette C1.

INKING:

- Anterior surface: Green.
- Anterior left surface: Blue.
- Posterior surface: Black.

GROSS PHOTOGRAPHS: Yes.

CASSETTES: Representative sections are submitted as follows:

- C1: Urethral margin, frozen remnant.
- C2: Ureter resection surface, en face (right ureter inked in green and left ureter inked in blue).
- C3: Urethral resection surface, en face.
- C4-C5: Perpendicular section through prostatic urethra and inferior bladder.
- C6-C9: Entire left lateral indurated mucosal area.
- C10: Entire posterior wall indurated mucosal area.
- C11-C14: Entire right trigone indurated mucosal area.
- C15: Representative section through central portion of bladder trigone.
- C16: Representative section from mid portion of bladder.
- C17: Representative section from bladder dome.
- C18: Left anterior prostate base, nodule.
- C19: Left posterior prostate and seminal vesicle.
- C20: Left anterior mid gland of prostate with irregular, yellow-white area.
- C21: Right posterior base of prostate and seminal vesicle.
- C22: Right mid gland of prostate.

[page 4 of 4]
C23: Candidate lymph nodes, submitted intact.
C24-C25: Nodule junction between left inferior bladder and prostate.
C26: Nodule junction between left inferior bladder and prostate, closest relationship to radial margin.

Part D, additionally labeled "right obturator nodes," consists of multiple, soft, tan-yellow fatty tissue fragments (3.5 x 2.5 x 1.5 cm in aggregate). The specimen is extensively searched for lymph nodes. Multiple candidate lymph nodes are found and submitted as follows:

Cassette D1: Three intact nodes.
Cassette D2: Three intact nodes.

Part E, additionally labeled "right internal iliac nodes," consists of multiple, soft, tan-yellow fatty tissue fragments (3 x 2 x 0.6 cm in aggregate). The specimen is extensively searched for lymph nodes. Two candidate nodes are found and submitted intact in cassette E1.

Part F, additionally labeled "left internal iliac lymph nodes," consists of multiple, soft, tan-yellow fatty tissue fragments (3.5 x 2 x 1 cm in aggregate). The specimen is extensively searched for lymph nodes. Multiple candidate lymph nodes are found and submitted as follows:

Cassette F1: Three intact nodes.
Cassette F2: One intact node.

Part G, additionally labeled "left obturator lymph nodes," consists of one, soft and firm, tan-yellow fatty tissue fragment (3.5 x 2 x 1 cm). The specimen is extensively searched for lymph nodes. Multiple candidate lymph nodes are found and submitted as follows:

Cassette G1: Three intact nodes.
Cassette G2: One intact node.

Part H, additionally labeled "final left distal ureter, stitch marks distal," consists of an oriented soft, tan and yellow segment of ureter (2 cm length, 0.4 cm average diameter). The specimen has a stitch at one end that is designated as the distal aspect by the surgeon. The stitch is removed and the area is inked blue. The specimen is cross-sectioned and entirely submitted in cassette H1.

Part I, additionally labeled "final right distal ureter, stitch marks distal," consists of one, soft, tan-yellow segment of ureter (3 cm length, 0.4 cm average diameter). The specimen is oriented with a stitch indicating the distal aspect. The stitch is removed and the area is inked blue. The specimen is cross-sectioned and entirely submitted in cassette I1.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Pathology Resident

Electronically signed out on /Pathologist

Let BCG given prior to
TC6A tumor procurement.

Source: NCI Genomic Data Commons file d2ea6a4a-64c6-459c-8709-a459c1a8db30 (TCGA-UY-A9PH.0F1A84D7-7EB5-4FDD-BB99-FC4DBB712814.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).